Gene-level copy-number profile of tumor specimen TCGA-25-1630-01A from TCGA case TCGA-25-1630, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.9 years (27,006 days).
Specimen TCGA-25-1630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.6ff06087-e0a3-4c0c-90d4-f30437d25f15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1630-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0c24b104-cd31-4dfc-bf8d-04502a9e8872

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 806; copy number 2: 11,241; copy number 3: 9,744; copy number 4: 30,314; copy number 5: 2,074; copy number 6: 2,569; copy number 7: 1,415; copy number 8: 1,486; copy number 9: 122; copy number 10: 32; copy number 12: 13; copy number 16: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1630-01): tumor purity 0.48, ploidy 3.77, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 168 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,426,263–213,284,205, 13 genes, copy number 9: MIR548F2, AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr3:108,032,456–108,039,916, 1 gene, copy number 16: AC012020.1.
- chr3:168,249,522–169,663,775, 13 genes, copy number 12 (within-gene range 7–12): EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1.
- chr3:171,815,586–173,336,965, 25 genes, copy number 9 (within-gene range 7–9): TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr6:453,391–909,006, 11 genes, copy number 10 (within-gene range 6–10): AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1.
- chr12:20,120,980–21,657,798, 21 genes, copy number 10 (within-gene range 8–10): LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2.
- chr17:75,205,659–76,643,786, 84 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
